Surgical pathology report (de-identified scan), TCGA case TCGA-06-0881, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0881-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

06-0881

CLINICAL HISTORY

Brain tumor

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, right temporal tumor, excision: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

The Ki-67 labeling index is approximately 8%. The MGMT promoter methylation assay is negative (see below).

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered:

Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Test performed on paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the laboratory as

[page 2 of 3]
[REDACTED]

required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, Temporal Lobe, biopsy: astrocytoma. Frozen section and smear preparations performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
SPECIMEN: Right temporal tumor
FIXATIVE: Unfixed
GENERAL: Received is a 2.0 x 1.2 x 0.3 cm aggregate of gray white to tan soft tissue fragments of brain tissue. Samples of these fragments are submitted for frozen section and smears.
SECTIONS: A1-FS frozen section remnant; 2-remainder of tissue

B.
SPECIMEN: Right temporal tumor, permanent
FIXATIVE:
GENERAL: A 1.5 x 1.5 x 1.3 cm irregular roughened fragment of tan to gray white brain tissue. Also received are smaller fragments of gray tan to tan red tissue ranging from 0.5-0.8 cm in greatest dimensions. Largest fragment sectioned.
SECTIONS: B1- smaller fragments; 2-3 larger fragment

[REDACTED]

MICROSCOPIC DESCRIPTION

Sections show a gemistocytic astrocytic tumor demonstrating vascular proliferation and pseudopalisading necrosis. Immunohistochemical stains reveal that the tumor is CD99 immunopositive (without distinct tumor cell membrane staining), NCAM immunopositive, and p53 immunonegative. The Ki-67 labeling index is approximately 8%.

ICD-9(s);
191.2 191.2

[REDACTED]

Histo Data

Part A: Brain biopsy

Taken: [REDACTED]

Stain/cnt

Received: [REDACTED]

Block Ordered Comment

[page 3 of 3]
[REDACTED]

FS H/E x 1	1
H/E x 1	1
TPS H/E x 1	1
H/E x 1	2

Part B: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
CD56-NO x 1	3	[REDACTED]	
H/E x 1	3	[REDACTED]	
MGMT x 1	3	[REDACTED]	
MIB1-DA x 1	3	[REDACTED]	
CD99-DA x 1	3	[REDACTED]	
P53D07 x 1	3	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file df57d011-6936-4940-8bf6-bdf8182b78a8 (TCGA-06-0881.ABDE276C-97E1-4FE4-BB86-EE20E65F7D5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).